Somatic mutation profile of tumor specimen TCGA-13-0912-01A (aliquot TCGA-13-0912-01A-01W-0420-08) from TCGA case TCGA-13-0912, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.7 years (21,427 days).
Specimen TCGA-13-0912-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bd5003d-9961-4380-bbd9-c3356cdb42aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0912-10A (Blood Derived Normal), aliquot TCGA-13-0912-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d2d3c3c-7e95-4db0-a6a5-37d68d7cac1f

The open-access MAF lists 43 somatic variants for this specimen: 29 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 24, Silent 14, Frame Shift Ins 2, Frame Shift Del 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.782+1G>A p.X261_splice | Splice Site (SNP) | VAF 286/373 reads (77%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACIN1 | c.970C>G p.P324A | Missense Mutation (SNP) | VAF 180/399 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV52976351; called by muse, mutect2, varscan2
- AGAP1 | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs969395658, COSV58320528; called by muse, mutect2, varscan2
- ANKRD27 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 110/232 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as rs201398434, COSV60131683; called by muse, mutect2, varscan2
- AP1G2 | c.1345dup p.A449Gfs*49 | Frame Shift Ins (INS) | VAF 10/77 reads (13%) | catalogued as rs749982998; called by mutect2, varscan2
- ARHGAP36 | c.1510C>A p.P504T | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as COSV52263750, COSV99357835; called by muse, mutect2
- ASIC4 | c.1101G>T p.M367I (on ENST00000347842 / NM_182847.3; = p.M386I on NM_018674.6) | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV61731828; called by muse, mutect2, varscan2
- ATP11C | c.2239C>T p.H747Y | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59564061; called by muse, mutect2
- EGFR | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 30/530 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1219568637, COSV51781835; called by muse, mutect2
- EPHA1 | c.2776C>G p.R926G | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); catalogued as CM1512494, COSV51971277; called by muse, mutect2, varscan2
- FAT3 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as rs1001662868, COSV53111028; called by muse, mutect2, varscan2
- FBXO9 | c.508del p.Q170Rfs*27 | Frame Shift Del (DEL) | VAF 92/278 reads (33%) | catalogued as COSV99762258; called by mutect2, pindel, varscan2
- GNB2 | c.302T>C p.M101T | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV51941879; called by muse, mutect2, varscan2
- HESX1 | c.193C>G p.P65A | Missense Mutation (SNP) | VAF 160/353 reads (45%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV55843274; called by muse, mutect2, varscan2
- IL17RB | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 138/286 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55472930; called by mutect2, varscan2
- KIF4B | c.1751C>A p.T584K | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV70529325; called by muse, mutect2
- KMT2A | c.6988A>G p.K2330E | Missense Mutation (SNP) | VAF 306/673 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); catalogued as COSV63285850; called by muse, mutect2, varscan2
- LLGL2 | c.1002_1016del p.F335_T339del | In Frame Del (DEL) | VAF 24/37 reads (65%) | catalogued as COSV51352811; called by mutect2, varscan2
- MCM5 | c.1702G>T p.V568L | Missense Mutation (SNP) | VAF 112/124 reads (90%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53346273; called by muse, mutect2, varscan2
- NEK10 | c.1702G>A p.V568I | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs370504122; called by muse, mutect2, varscan2
- NLGN1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.555); catalogued as COSV100849516; called by muse, mutect2
- NR1H4 | c.905C>T p.T302M (on ENST00000551379 / NM_001206993.2; = p.T288M on NM_005123.4) | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs748378207, COSV51852131; called by muse, mutect2, varscan2
- PCDHB2 | c.2192A>T p.E731V | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.729); catalogued as COSV99165556; called by muse, mutect2, varscan2
- PLIN2 | c.1187C>A p.T396K | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52802571, COSV52803264; called by muse, mutect2, varscan2
- SGSM1 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 129/145 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1361949539, COSV68508552, COSV68512419; called by muse, mutect2, varscan2
- SH3RF2 | c.1987G>A p.G663R | Missense Mutation (SNP) | VAF 138/288 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as rs142456711; called by muse, mutect2, varscan2
- WDR5B | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 146/317 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.471); catalogued as COSV51658132; called by muse, mutect2, varscan2
- ZZZ3 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 179/361 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV66232760; called by muse, mutect2, varscan2
- ASXL1 | c.2920dup p.Y974Lfs*8 | Frame Shift Ins (INS) | VAF 43/119 reads (36%) | called by mutect2, pindel, varscan2
- ARHGAP36 | c.1509G>A p.V503= | Silent (SNP) | VAF 7/182 reads (4%) | catalogued as rs1285422410, COSV99357831; called by muse, mutect2
- DNAH1 | c.3573C>T p.D1191= | Silent (SNP) | VAF 139/287 reads (48%) | catalogued as rs541334137, COSV70229070; ClinVar: likely benign; called by muse, mutect2, varscan2
- FKBP5 | c.111C>G p.V37= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV61881762; called by muse, mutect2, varscan2
- ITPRID1 | c.858C>T p.P286= | Silent (SNP) | VAF 54/126 reads (43%) | catalogued as rs1278810096, COSV60074915; called by mutect2, varscan2
- MAP1B | c.858C>T p.G286= | Silent (SNP) | VAF 187/452 reads (41%) | catalogued as rs777817448, COSV57099167; called by muse, mutect2, varscan2
- OXSM | c.972C>G p.A324= | Silent (SNP) | VAF 103/224 reads (46%) | catalogued as COSV55001527; called by muse, mutect2, varscan2
- PCDHB9 | c.1341C>T p.N447= | Silent (SNP) | VAF 79/170 reads (46%) | catalogued as rs1459171550, COSV53376231; called by muse, mutect2, varscan2
- PDE11A | c.2070C>G p.T690= | Silent (SNP) | VAF 31/229 reads (14%) | catalogued as rs758882128, COSV53692777, COSV99610753, COSV99613144; called by muse, mutect2, varscan2
- PRKAR1B | c.663C>T p.L221= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV100816738; called by muse, mutect2, varscan2
- RGS7 | c.87C>T p.D29= | Silent (SNP) | VAF 66/140 reads (47%) | catalogued as rs563733368, COSV58542082; called by muse, mutect2, varscan2
- SNX33 | c.1287G>A p.Q429= | Silent (SNP) | VAF 74/144 reads (51%) | catalogued as COSV57913528; called by muse, mutect2, varscan2
- THADA | c.4488A>T p.G1496= | Silent (SNP) | VAF 62/150 reads (41%) | catalogued as COSV57683734; called by muse, mutect2, varscan2
- TTC38 | c.633G>T p.P211= | Silent (SNP) | VAF 80/97 reads (82%) | catalogued as COSV66844225; called by muse, mutect2, varscan2
- ZNF813 | c.1068G>A p.K356= | Silent (SNP) | VAF 379/872 reads (43%) | catalogued as COSV67176551; called by muse, mutect2, varscan2
